Gene-level copy-number profile of tumor specimen TCGA-BC-A3KF-01A from TCGA case TCGA-BC-A3KF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.6 years (24,328 days).
Specimen TCGA-BC-A3KF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.065f4be9-5b0d-4a94-9274-04c9a0fc7dd4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A3KF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ef54c773-d231-4b55-a461-02021473d1f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 13,147; copy number 2: 38,333; copy number 3: 7,376; copy number 4: 324; copy number 5: 231; copy number 6: 266; copy number 7: 61; copy number 10: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A3KF-01A-11D-A20V-01): tumor purity 0.83, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:147,732,063–148,072,776, 1 gene (within-gene range 0–1): ARHGAP10.
- chr4:147,808,926–149,024,624, 9 genes (within-gene range 0–2): RN7SL254P, AC115621.1, NR3C2, AC069272.1, AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 627 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:53,377,839–54,295,272, 1 gene, copy number 5 (within-gene range 2–5): AC058822.1.
- chr4:53,899,871–56,328,625, 51 genes, copy number 5 (within-gene range 3–5): AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161.
- chr8:46,028,804–51,809,445, 80 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr13:88,978,447–95,579,759, 72 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr13:95,677,139–95,794,988, 1 gene, copy number 6 (within-gene range 4–6): DNAJC3.
- chr13:95,744,726–114,337,626, 292 genes, copy number 5–6 (broad region; genes not listed).
- chr15:99,565,417–101,933,350, 69 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr17:16,191,832–17,242,886, 61 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,403. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
